CCG case CUPP-B7FH — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86560b61-0603-484a-903f-c9bbb9b04166

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 906 days (2.5 years); Year of death: 2004; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Large cell neuroendocrine carcinoma: ICD-O-3 morphology code: 8013/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2001; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: First-Line Therapy.
   Recorded as not given: first-line therapy Hormone Therapy; first-line therapy Immunotherapy (Including Vaccines); first-line therapy Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 906 days (2.5 years); Year of follow up: 2004.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7FH-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7FH-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
